Surgical pathology report (de-identified scan), TCGA case TCGA-86-8056, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8056-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

ID	Gross Description
	A. Labeled lymph node 10R. There is a 1.4 x 0.7 cm dark gray lymph node with a small amount attached pale yellow adipose tissue. B. Labeled right upper lobe. Received fresh for intraoperative consultation is a 28 g stapled wedge of lung measuring 6.7 x 4.2 x 2.3 cm. The pleural surface is dark gray to pale tan with subtle puckering and previous incision near the midpoint. Upon sectioning, the cut surfaces are tan to red and spongy with a 1.9 x 1.3 cm poorly-defined, firm pale tan subpleural nodule, located 1.0 cm from the stapled edge. Sampled for frozen section. No other lesions are noted. C. Labeled lymph node 9. There is a 0.7 cm dark gray lymph node with attached fat. D. Labeled lymph node 4R. There is a 2.9 x 2.0 x 0.8 cm portion of tan fibroadipose tissue containing 2 possible lymph nodes measuring 0.5 x 0.3 cm and 1.5 x 0.8 cm. Upon sectioning, the cut surfaces of the larger are gray to black and smooth. E. Labeled right upper lobe sump. There is a 1.1 x 0.9 cm black and tan soft tissue fragment. Entirely submitted in one cassette. F. Labeled lymph node R7. There are 2 dark gray to black soft tissue fragments with attached adipose tissue measuring 1.6 x 1.0 x 0.7 cm and 2.5 x 1.2 x 1.0 cm. G. Labeled right lower lobe with margins on bronchus. Received fresh for intraoperative consultation is a 165 g lobe of lung measuring 13.5 x 13 x 5 cm. The pleural surface is tan to pale gray, lightly wrinkled and glistening with a 3.2 x 2.5 cm ovoid subpleural mass with a slightly raised and somewhat scalloped rim surrounding a flat center. Upon sectioning, the subpleural mass is up to 1.5 cm thick with pale tan cut surfaces showing central cavitation. The mass comes to within 5 cm of the bronchial margin, which is shaved and submitted for frozen section. The background parenchyma is red and spongy with cystic spaces up to 1.7 cm along the periphery of the base. Within the hilum is a 0.8 cm black lymph node. H. Labeled R11 lymph node. There is a 1.5 x 0.9 cm brown to dark gray lymph

[page 2 of 3]
Microscopic Description	Diagnosis Details	Comments
A. Microscopic performed. B. Sections reveal an invasive adenocarcinoma, mixed subtype with acinar and lepidic growth patterns. The invasive acinar component measures 0.7 cm within a tumor displaying a prominent lepidic pattern. There is extensive subpleural scar formation with both the frozen section slide and the permanent slide of the frozen section demonstrating the extensive scar. The invasive adenocarcinoma is predominantly present on the adjacent section submitted for permanent section evaluation (block B2). For additional details please see the checklist. C-F. Microscopic performed. G. Sections reveal an invasive adenocarcinoma, mixed subtype with papillary, acinar, lepidic, micropapillary, and solid growth patterns (predominant pattern is papillary). One benign anthracotic lymph node is also identified. A special stain for elastin was performed with appropriate controls. It supports the initial H&E interpretation of subpleural involvement. For additional details please see the checklist. H. Microscopic performed.	LUNG CARCINOMA CHECKLIST  1. Tumor Type: Adenocarcinoma. 2. Tumor grade: Poorly differentiated. 3. Tumor location: 2 separate invasive tumors, right lower lobe and right upper lobe. 4. Tumor size: Largest primary, 3.2 cm, right lower lobe. 5. Angiolymphatic invasion: Present. 6. Bronchial margin: Free of tumor (tumor grossly 5 cm from bronchial margin). 7. Pleural involvement: Subpleura. 8. Lymph nodes: 0 positive out of 9 found. 9. Size of largest metastatic deposit: N/A. 10. pTNM: pT4 (separate tumor nodule in a different ipsilateral lobe) N0 MX. 	A. Lymph node level 10 R, biopsy: One benign lymph node. (0/1) B. Lung, right upper lobe, wedge resection: Invasive adenocarcinoma, mixed subtype. (See description and checklist) C. Lymph node level 9, biopsy: One benign lymph node. (0/1) D. Lymph node level 4 R, biopsy: Two benign lymph nodes. (0/2) E. Lymph node, right upper lobe sump, biopsy: One benign lymph node. (0/1) F. Lymph node level 7 R, biopsy: Two benign lymph nodes. (0/2) G. Lung, right lower lobe, lobectomy: Invasive adenocarcinoma, mixed subtype. (See description and checklist) One benign lymph node. (0/1) H. Lymph node level R 11, biopsy: One benign lymph node. (0/1)

[page 3 of 3]
Formatted Path Report	Lateralit y/locati on	OpenCli nica ID	Date of excision
LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3.2 x 5 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Yes - Lymph nodes: 0/9 positive for metastasis (Pulmonary 0/9) Lymphatic invasion: Present Venous invasion: Present Margins: Not specified Evidence of neo- adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Right- upper		

Source: NCI Genomic Data Commons file dd26279d-abe5-4af5-98ea-0d66abb79be3 (TCGA-86-8056.B372FD6D-8C36-4642-B660-D353EFB0BD89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).